Gene-level copy-number profile of tumor specimen TCGA-93-8067-01A from TCGA case TCGA-93-8067, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.9 years (28,453 days).
Specimen TCGA-93-8067-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.74402b4a-1429-445b-98fa-f1950f04810e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-93-8067-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2bdefa7-ff9d-4538-9100-d408afe1b2ae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 504; copy number 2: 7,090; copy number 3: 10,176; copy number 4: 17,881; copy number 5: 12,992; copy number 6: 7,486; copy number 7: 1,513; copy number 8: 289; copy number 9: 403; copy number 10: 1,384; copy number 12: 55; copy number 13: 18; copy number 14: 8; copy number 18: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-93-8067-01A-11D-2283-01): tumor purity 0.32, ploidy 4.4, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:14,274,622–14,274,725, 1 gene: RNU6-1288P.
- chr22:25,327,252–25,520,854, 9 genes (within-gene range 0–2): AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,875 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:81,334,303–81,334,418, 1 gene, copy number 9: RNU5A-2P.
- chr4:170,979,831–171,638,763, 9 genes, copy number 9: AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1.
- chr4:176,012,038–190,092,279, 216 genes, copy number 9–18 (broad region; genes not listed).
- chr6:127,266,682–128,520,616, 20 genes, copy number 9 (within-gene range 4–9): RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1.
- chr6:137,543,897–137,544,372, 1 gene, copy number 9: BTF3L4P3.
- chr6:137,693,068–137,700,415, 1 gene, copy number 9: AL356234.3.
- chr8:40,900,016–145,066,685, 1,616 genes, copy number 9–13 (broad region; genes not listed).
- chr10:4,747,846–5,135,226, 11 genes, copy number 9–14 (within-gene range 6–14): AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.

Autosomal genes at a single copy (total copy number 1): 504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
